Somatic mutation profile of tumor specimen 358296ad-e2a7-40cd-849e-8590fd (aliquot 358296ad-e2a7-40cd-849e-8590fd_D6_1) from CPTAC case 20BR001, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 81.9 years (29,929 days).
Specimen 358296ad-e2a7-40cd-849e-8590fd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b68610ff-f129-4da1-8649-8fdf8d912457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen cee1c3f1-6fab-4d2c-9982-27406d (Blood Derived Normal), aliquot cee1c3f1-6fab-4d2c-9982-27406d_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/904808f7-1077-442d-a64c-503b372136d9

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Intron 4, 5'UTR 2, Nonsense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.1828T>C p.S610P | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as COSV62814443; called by muse, mutect2, varscan2
- CSMD3 | c.2434C>T p.Q812* (on ENST00000297405 / NM_001363185.1; = p.Q708* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 33/239 reads (14%) | catalogued as COSV52116928; called by muse, mutect2, varscan2
- ERAP1 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs146386179; called by muse, mutect2, varscan2
- LILRA4 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs752309890, COSV52490593; called by muse, mutect2
- OR4N5 | c.656C>G p.A219G | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV61320562; called by muse, mutect2, varscan2
- RLF | c.3968A>G p.N1323S | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.191); catalogued as rs762703786; called by muse, varscan2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 207/717 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4C | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 107/332 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs201014435; called by muse, mutect2, varscan2
- TEKT3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs776165938, COSV58629436; called by muse, mutect2, varscan2
- UHRF2 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs776656325, COSV52793580; called by muse, mutect2, varscan2
- WIPI2 | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV56588914; called by muse, varscan2
- B3GAT2 | c.968T>A p.V323E | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CAMSAP2 | c.4085A>C p.K1362T (on ENST00000236925 / NM_001297707.2; = p.K1351T on NM_203459.3) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTLN | c.3401A>T p.E1134V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- COL14A1 | c.1745T>C p.V582A | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- DNAJC13 | c.1921T>C p.W641R | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DOCK8 | c.1072A>T p.I358F | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DPY19L1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ERVV-1 | c.590T>A p.L197Q | Missense Mutation (SNP) | VAF 147/414 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- FAM47C | c.332A>T p.Q111L | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- GNAT1 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 70/983 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GTF3C3 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- KIF1A | c.4018G>C p.V1340L (on ENST00000320389 / NM_001379639.1; = p.V1332L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- KMT2C | c.7022del p.P2341Qfs*24 | Frame Shift Del (DEL) | VAF 123/237 reads (52%) | called by mutect2, pindel, varscan2
- NR2C2 | c.1700T>C p.I567T (on ENST00000393102; = p.I586T on NM_003298.5) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR14K1 | c.634A>T p.I212F | Missense Mutation (SNP) | VAF 148/521 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SCN8A | c.1364C>A p.A455E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.915); called by muse, varscan2
- HES3 | c.348G>A p.L116= | Silent (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- ACADL | c.372-31G>T | Intron (SNP) | VAF 11/173 reads (6%) | called by muse, mutect2
- ATP6V1B2 | c.137-516T>A | Intron (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- CSHL1 | c.-17C>A | 5'UTR (SNP) | VAF 37/208 reads (18%) | catalogued as COSV51988118; called by muse, mutect2, varscan2
- IDI1 | c.537+61T>G | Intron (SNP) | VAF 64/187 reads (34%) | called by muse, mutect2, varscan2
- NOTCH2NLA | c.-59C>T | 5'UTR (SNP) | VAF 15/83 reads (18%) | catalogued as rs782724090; called by muse, mutect2, varscan2
- U2AF1L4 | c.578+134T>A | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
